Somatic mutation profile of tumor specimen TCGA-EE-A20F-06A (aliquot TCGA-EE-A20F-06A-21D-A196-08) from TCGA case TCGA-EE-A20F, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.3 years (21,675 days).
Specimen TCGA-EE-A20F-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2ea6ca3-275b-4457-85f6-39eab00b774f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A20F-10A (Blood Derived Normal), aliquot TCGA-EE-A20F-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b245782-ba86-42d8-806c-0567ad6372d2

The open-access MAF lists 561 somatic variants for this specimen: 355 protein-altering or splice-affecting, 190 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 190, Nonsense Mutation 22, RNA 6, Intron 5, 3'UTR 5, Frame Shift Del 4, Splice Site 4, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KMT2D | c.16295G>A p.R5432Q | Missense Mutation (SNP) | VAF 69/195 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123734, CM126446, COSV56409187, COSV99985294; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by mutect2, varscan2
- AADAC | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51759237; called by muse, varscan2
- AADACL4 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV100879523, COSV66106258; called by muse, mutect2, varscan2
- ABRA | c.97T>A p.W33R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732388; called by muse, varscan2
- ABRA | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs769633887, COSV61732395; called by muse, varscan2
- ACKR3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1004885299, COSV56020945; called by mutect2, varscan2
- ACSM2A | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.343); catalogued as COSV54584620, COSV99525817; called by muse, mutect2, varscan2
- ADAM18 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV55846081; called by mutect2, varscan2
- ADAM7 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.305); catalogued as COSV51539835; called by mutect2, varscan2
- ADAMTS12 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV61262789; called by muse, mutect2, varscan2
- ADAMTS19 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV99178827; called by mutect2, varscan2
- ADGRV1 | c.11732G>A p.G3911E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67980306, COSV67983529; called by mutect2, varscan2
- ADPRHL1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV62910215; called by muse, mutect2, varscan2
- ADSS1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58273399; called by muse, mutect2, varscan2
- AGFG1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59511851, COSV59514152; called by muse, mutect2, varscan2
- AGTR1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM045868, COSV62558166; called by muse, mutect2, varscan2
- AKAP8L | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV68473509; called by muse, mutect2, varscan2
- AKR1C8P | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782328101; called by muse, mutect2, varscan2
- AKR7A2 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV52516137; called by muse, mutect2, varscan2
- AL136295.1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55779496; called by muse, mutect2, varscan2
- ANK3 | c.7768G>A p.E2590K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55057411, COSV99778550; called by mutect2, varscan2
- ANK3 | c.3187G>A p.E1063K (on ENST00000280772 / NM_001320874.2; = p.E197K on NM_001149.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55057421; called by muse, mutect2, varscan2
- AP1G1 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55489083; called by mutect2, varscan2
- APLP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV55703311; called by muse, mutect2, varscan2
- APP | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.406); catalogued as COSV60998368; called by mutect2, varscan2
- ARMC4 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV59463181; called by muse, mutect2, varscan2
- BAG6 | c.2165C>T p.P722L (on ENST00000676571; = p.P675L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs780725341, COSV52990554; called by muse, mutect2, varscan2
- BCAR1 | c.1798A>T p.N600Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50782899; called by muse, mutect2, varscan2
- BCO1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50729592; called by muse, mutect2, varscan2
- BOD1L1 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV50012922; called by muse, mutect2, varscan2
- BSG | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.915); catalogued as rs1241844764, COSV61076919; called by muse, mutect2, varscan2
- BSN | c.10409G>A p.R3470Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs142290203; called by muse, mutect2, varscan2
- C10orf71 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); catalogued as rs758472555, COSV60507579, COSV60509749; called by mutect2, varscan2
- C16orf71 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV54788113; called by muse, mutect2, varscan2
- C17orf49 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV66080942; called by muse, mutect2, varscan2
- C1QL3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54348696; called by muse, mutect2, varscan2
- C1orf141 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.72); catalogued as COSV63992623; called by muse, mutect2, varscan2
- C5 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs537101618, COSV56327108; called by muse, mutect2, varscan2
- C8orf34 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV61379409; called by mutect2, varscan2
- C9orf152 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV68762855; called by muse, mutect2, varscan2
- CACNA1G | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs763375795, COSV61720829; called by muse, mutect2, varscan2
- CCDC33 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58351695; called by muse, mutect2, varscan2
- CCNF | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99563625; called by muse, mutect2, varscan2
- CD163 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63132183; called by muse, mutect2, varscan2
- CD1A | c.883+2T>C p.X295_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV56861731; called by muse, varscan2
- CDC37 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55768302; called by muse, mutect2, varscan2
- CDH18 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV56913618; called by muse, mutect2, varscan2
- CDX4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65171547; called by muse, varscan2
- CELF1 | c.1156C>T p.Q386* (on ENST00000358597 / NM_001376422.1; = p.Q382* on NM_006560.4 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV60111953; called by mutect2, varscan2
- CHRM2 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.103); catalogued as rs527857234, COSV57772036; called by muse, mutect2, varscan2
- CHST15 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV60562107; called by muse, mutect2, varscan2
- CLGN | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV57774642; called by muse, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, varscan2
- CNTN6 | c.2423G>A p.G808E | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT tolerated (0.72); PolyPhen probably damaging (1); catalogued as rs376986203; called by muse, mutect2, varscan2
- COL11A1 | c.1570C>T p.R524W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771139447, COSV62178322; called by mutect2, varscan2
- COL1A1 | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV56804805; called by muse, mutect2, varscan2
- COL23A1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs1333797290, COSV66790468; called by muse, mutect2
- COL4A1 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV65425490; called by muse, varscan2
- COMP | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1282794305, COSV55874771; called by mutect2, varscan2
- CPA3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199600994, COSV56044010; called by mutect2, varscan2
- CPNE1 | c.559C>T p.P187S (on ENST00000352393; = p.P192S on NM_003915.5) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100467539; called by muse, mutect2, varscan2
- CPT1C | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54919148; called by muse, mutect2, varscan2
- CSMD1 | c.9572C>T p.S3191F (on ENST00000520002; = p.S3190F on NM_033225.6) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59322410; called by muse, mutect2, varscan2
- CUX2 | c.3645G>T p.W1215C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55626452, COSV55631716; called by muse, mutect2, varscan2
- CXCR6 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99945684; called by muse, mutect2, varscan2
- CXCR6 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99945685; called by muse, mutect2, varscan2
- CYP46A1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1311555924, COSV55894506; called by muse, mutect2, varscan2
- DBR1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 142/597 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV53429758; called by muse, mutect2, varscan2
- DEFB105A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV58294716; called by mutect2, varscan2
- DENND2B | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV58203553; called by muse, mutect2, varscan2
- DHDH | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV55482120; called by muse, mutect2, varscan2
- DIP2A | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs375904809; called by mutect2, varscan2
- DIPK2B | c.440A>T p.K147I | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV65005267; called by mutect2, varscan2
- DMBT1 | c.5584G>A p.E1862K (on ENST00000338354 / NM_001377530.1; = p.E1105K on NM_004406.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs1045906158, COSV57534249; called by mutect2, varscan2
- DNAH1 | c.5162C>T p.S1721F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375094563, COSV70227251; called by muse, mutect2, varscan2
- DNAH11 | c.613A>G p.K205E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV60955332; called by muse, mutect2, varscan2
- DNAH17 | c.9526G>A p.G3176S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765917301, COSV67754160; called by muse, mutect2, varscan2
- DNAH3 | c.9734T>C p.V3245A | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54521028; called by muse, mutect2, varscan2
- DNAH5 | c.10875C>T p.I3625= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as rs772138612, COSV54223956; called by mutect2, varscan2
- DNAH5 | c.6719C>T p.P2240L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV54223967; called by muse, mutect2, varscan2
- DPH1 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV53984601; called by muse, mutect2, varscan2
- DPP6 | c.283G>A p.G95R (on ENST00000377770 / NM_001364500.2; = p.G33R on NM_001936.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59612494; called by muse, mutect2, varscan2
- DSC3 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64572922; called by muse, mutect2, varscan2
- DZIP1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV61265734; called by muse, mutect2, varscan2
- EDC3 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV59340169; called by muse, varscan2
- EDEM3 | c.786A>C p.K262N | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV58924354; called by muse, mutect2, varscan2
- EFL1 | c.2172T>G p.D724E | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs756559129, COSV51605411; called by muse, varscan2
- EGF | c.791G>C p.W264S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV54475790, COSV54482590; called by muse, mutect2, varscan2
- EPB42 | c.972G>A p.W324* (on ENST00000441366 / NM_001114134.2; = p.W354* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV55749609; called by muse, mutect2, varscan2
- EPHA3 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100345353; called by muse, mutect2, varscan2
- EPHA6 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67571678, COSV67587508; called by muse, mutect2, varscan2
- ERG | c.1380G>A p.W460* (on ENST00000398919 / NM_001243428.1; = p.W436* on NM_004449.4) | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55727753; called by muse, mutect2, varscan2
- ERICH3 | c.1804del p.D602Tfs*22 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs779324406; called by mutect2, pindel
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by mutect2, varscan2
- FAM171A1 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1023492804, COSV65315982; called by muse, mutect2, varscan2
- FAT4 | c.5011C>T p.R1671C | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as rs373116363, COSV67881470, COSV67885210; called by mutect2, varscan2
- FBLN7 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV55615449, COSV55616179; called by muse, mutect2, varscan2
- FGF18 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV51126314; called by muse, mutect2, varscan2
- FLG | c.3524G>A p.G1175E | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs774531820, COSV64241724; called by muse, mutect2, varscan2
- FNDC1 | c.4924G>A p.E1642K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs267600882, COSV51937639; called by mutect2, varscan2
- FNDC1 | c.5630C>T p.P1877L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51937655; called by muse, mutect2, varscan2
- FOXA1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51643748; called by mutect2, varscan2
- FREM2 | c.4400G>T p.G1467V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54837420; called by muse, mutect2, varscan2
- FRMPD3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99346344; called by muse, mutect2, varscan2
- FRY | c.8035G>A p.D2679N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs781431979, COSV66570062; called by mutect2, varscan2
- FSHR | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as COSV58623355, COSV58638397; called by muse, mutect2, varscan2
- FTHL17 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV63266778, COSV63267286; called by mutect2, varscan2
- FYB2 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs767925458, COSV58585039; called by mutect2, varscan2
- GABRA6 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50880815, COSV50880927; called by muse, mutect2, varscan2
- GABRG1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54953928; called by muse, mutect2, varscan2
- GABRG1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV54953934, COSV99777743; called by mutect2, varscan2
- GBE1 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70099266; called by muse, mutect2
- GJB7 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51529707; called by mutect2, varscan2
- GLB1L2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60278559; called by muse, mutect2, varscan2
- GLYATL2 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV54849889; called by muse, mutect2, varscan2
- GNG7 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV66285614; called by muse, mutect2, varscan2
- GOLGA6B | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69770628; called by muse, mutect2, varscan2
- GPR139 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58502854; called by muse, mutect2, varscan2
- GPR141 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759565313, COSV57731278, COSV57732248; called by mutect2, varscan2
- GPR179 | c.889G>A p.D297N (on ENST00000621958; = p.D296N on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs867593960; called by mutect2, varscan2
- GRIA4 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775109537, COSV56895829; called by muse, mutect2, varscan2
- GRID2 | c.1873T>A p.Y625N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV56204423; called by muse, mutect2, varscan2
- GRIN2A | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58032210, COSV58055529; called by muse, mutect2, varscan2
- GRM8 | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58825161; called by muse, mutect2, varscan2
- HEATR6 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51744359, COSV51745654; called by muse, mutect2, varscan2
- HECW1 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV67829223; called by mutect2, varscan2
- HIVEP3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV56015347; called by muse, mutect2, varscan2
- HSD17B4 | c.1433T>C p.L478P (on ENST00000414835 / NM_001199291.3; = p.L453P on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV56335638; called by muse, mutect2, varscan2
- HTR5A | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1359995825, COSV55280803; called by muse, mutect2, varscan2
- HTT | c.4040C>T p.S1347F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61861727; called by muse, mutect2, varscan2
- HYDIN | c.9254C>T p.S3085F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as COSV59256947; called by muse, mutect2, varscan2
- IGHG3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1458265564; called by muse, varscan2
- IGHV3-30 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.061); catalogued as rs778939031; called by mutect2, varscan2
- IGKV1-16 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs750862644; called by muse, varscan2
- ILDR2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as COSV54830867; called by muse, mutect2, varscan2
- ISLR | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.185); catalogued as COSV51433815; called by mutect2, varscan2
- ITGA8 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65228699; called by muse, mutect2, varscan2
- JAGN1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs755171967, COSV57061948; called by muse, mutect2, varscan2
- JAK3 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV71686045; called by muse, mutect2, varscan2
- KALRN | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53763533; called by muse, mutect2, varscan2
- KDR | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV55764902; called by muse, mutect2, varscan2
- KIAA0100 | c.4370C>T p.S1457F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV66492677; called by muse, mutect2, varscan2
- KIAA0930 | c.1052C>T p.S351F (on ENST00000336156 / NM_001009880.2; = p.S356F on NM_015264.2) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV52662188; called by muse, mutect2, varscan2
- KIF13B | c.3064C>T p.Q1022* | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as COSV72954393; called by muse, mutect2, varscan2
- KIF1C | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57903546; called by muse, mutect2, varscan2
- KLF12 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV66573281; called by muse, mutect2, varscan2
- KLKB1 | c.869-1G>A p.X290_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as COSV52995619; called by muse, mutect2, varscan2
- KPNA2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as COSV57857547; called by muse, mutect2, varscan2
- KRT28 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV60685085; called by muse, mutect2, varscan2
- KRT84 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs747946695, COSV57770506; called by muse, mutect2, varscan2
- KRTAP5-11 | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59369042; called by muse, mutect2, varscan2
- LAMA3 | c.7585C>T p.L2529F (on ENST00000313654 / NM_198129.4; = p.L920F on NM_000227.6) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52534508; called by muse, mutect2, varscan2
- LCP2 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs745596318, COSV99252763; called by muse, mutect2
- LGALS12 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs763457323, COSV55370263; called by mutect2, varscan2
- LILRB2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58745211; called by muse, varscan2
- LPAR4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606517, COSV70912599; called by muse, varscan2
- LRP1B | c.10519G>A p.E3507K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67218419; called by mutect2, varscan2
- LRRC27 | c.693T>A p.F231L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV59808832; called by mutect2, varscan2
- LRRC4C | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1438147678, COSV53425444; called by mutect2, varscan2
- MAK | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57565275; called by muse, mutect2, varscan2
- MARCO | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV59054240; called by muse, mutect2, varscan2
- MATK | c.1383G>A p.W461* (on ENST00000310132 / NM_139355.3; = p.W462* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV59554498; called by muse, mutect2, varscan2
- MBTD1 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64503351, COSV64503652; called by muse, mutect2, varscan2
- MDGA1 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs529793835, COSV51795888; called by muse, mutect2
- METTL4 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55247947; called by muse, mutect2, varscan2
- MKRN3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs781005844, COSV58808823; called by mutect2, varscan2
- MLXIPL | c.2040T>A p.S680R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV57668133; called by muse, mutect2
- MOV10L1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53171182; called by muse, mutect2, varscan2
- MROH2B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451889213, COSV101270575, COSV101270679; called by muse, mutect2, varscan2
- MSH5 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777634800, COSV65209628; called by mutect2, varscan2
- MUC16 | c.25502C>T p.S8501F | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as COSV67448477, COSV67465137; called by muse, mutect2, varscan2
- MUC16 | c.3883G>A p.A1295T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV67465144; called by muse, mutect2, varscan2
- MYH4 | c.5278A>G p.K1760E | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV55118048; called by muse, mutect2, varscan2
- MYO16 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51793328; called by muse, mutect2, varscan2
- MYO5B | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as COSV53218355, COSV53218561; called by muse, varscan2
- MYOM3 | c.4078G>A p.G1360R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58393620; called by muse, mutect2, varscan2
- NAP1L2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV65172496; called by muse, mutect2, varscan2
- NEXMIF | c.3813G>A p.M1271I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as COSV50030619; called by mutect2, varscan2
- NIN | c.3646C>T p.R1216* | Nonsense Mutation (SNP) | VAF 36/107 reads (34%) | catalogued as rs779341516, COSV55389953; called by muse, mutect2, varscan2
- NOVA1 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as COSV57476570; called by muse, mutect2, varscan2
- NOX5 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52988722, COSV52992647; called by muse, mutect2, varscan2
- NPW | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61586157; called by muse, mutect2, varscan2
- NSUN7 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV57273764; called by muse, mutect2, varscan2
- NUP153 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1261865277, COSV50449438; called by muse, mutect2, varscan2
- OR11H12 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs267603905, COSV101612492; called by mutect2, varscan2
- OR13D1 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV59513792; called by muse, mutect2, varscan2
- OR4A47 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV71444936; called by muse, mutect2, varscan2
- OR4C11 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV56353162; called by muse, mutect2, varscan2
- OR4S1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60678732; called by muse, mutect2, varscan2
- OR51A4 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs770854830, COSV66749129; called by muse, varscan2
- OR51A4 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.151); catalogued as rs750620171, COSV66749436; called by muse, mutect2, varscan2
- OR51E2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs867888582, COSV67806638; called by muse, varscan2
- OR5J2 | c.488T>G p.L163W | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56621194; called by muse, mutect2, varscan2
- OR5T1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs371059328, COSV57302248; called by mutect2, varscan2
- OR7G2 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1332899328, COSV59687921; called by mutect2, varscan2
- OR8G1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); catalogued as rs368405472; called by mutect2, varscan2
- OTOGL | c.2860C>T p.R954* (on ENST00000547103; = p.R945* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | catalogued as rs572666403, COSV72006450; called by muse, mutect2, varscan2
- OTUD6A | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0.227); catalogued as rs1465157091, COSV57973338; called by mutect2, varscan2
- OTX2 | c.649G>A p.A217T (on ENST00000408990 / NM_172337.3; = p.A225T on NM_021728.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs750626422, COSV59766036; called by muse, mutect2, varscan2
- OXR1 | c.1226T>C p.L409S (on ENST00000442977 / NM_001198532.1; = p.L408S on NM_018002.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as rs1276521299, COSV56328830; called by muse, mutect2, varscan2
- PADI3 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV64934536; called by muse, mutect2, varscan2
- PAH | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as rs868854935, COSV61013953; called by mutect2, varscan2
- PARP6 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53003188; called by mutect2, varscan2
- PARVG | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100796079, COSV63561953; called by muse, varscan2
- PCDHA1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.295); catalogued as COSV65374266; called by muse, mutect2, varscan2
- PCDHA6 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as rs1554132256, COSV65344061; called by muse, mutect2, varscan2
- PCDHB6 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV50689835; called by muse, mutect2, varscan2
- PCDHGA5 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs1245270195, COSV53927305, COSV99548610; called by mutect2, varscan2
- PCLO | c.15324A>T p.K5108N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61634616, COSV61654036; called by muse, mutect2, varscan2
- PCLO | c.11240C>T p.S3747F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61634620; called by muse, mutect2, varscan2
- PDE1C | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.108); catalogued as rs752243504, COSV58513543; called by muse, mutect2, varscan2
- PEAK1 | c.3181C>T p.P1061S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV56935221; called by muse, mutect2, varscan2
- PEAK1 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56935239; called by muse, mutect2, varscan2
- PGBD1 | c.1166G>C p.S389T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV52553346; called by muse, mutect2, varscan2
- PHF24 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1402364683, COSV54272950; called by mutect2, varscan2
- PIK3CG | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as rs762805000, COSV63245782; called by mutect2, varscan2
- PITPNM2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV54900648; called by muse, mutect2, varscan2
- PJA2 | c.1116C>G p.D372E | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1341157034, COSV63272777; called by muse, mutect2, varscan2
- PKD1L2 | c.2437G>A p.G813S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV55161911; called by muse, mutect2, varscan2
- PKHD1L1 | c.4757G>A p.G1586E | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV65742759; called by muse, mutect2, varscan2
- PKHD1L1 | c.10456G>A p.D3486N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV65742781; called by muse, mutect2, varscan2
- PLCB4 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs866533934, COSV53796419; called by muse, mutect2, varscan2
- PLCH1 | c.1416C>A p.C472* (on ENST00000340059 / NM_001130960.2; = p.C484* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/159 reads (25%) | catalogued as COSV58196936; called by muse, mutect2, varscan2
- POLN | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV67025255; called by muse, mutect2, varscan2
- PPARGC1B | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs746361969, COSV58529181; called by muse, mutect2, varscan2
- PPFIA2 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV61027580; called by mutect2, varscan2
- PPP1R3A | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as COSV52882407; called by muse, mutect2, varscan2
- PRKAA2 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV64803706; called by muse, mutect2, varscan2
- PSG1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV54947585, COSV99740354; called by mutect2, varscan2
- PTGDR | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV60093798; called by muse, mutect2, varscan2
- PTPN13 | c.6113C>T p.P2038L (on ENST00000411767 / NM_080683.3; = p.P2019L on NM_006264.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57407336; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV57928875; called by mutect2, varscan2
- RASSF9 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1391266717, COSV63433605; called by muse, varscan2
- REG1B | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59305573; called by muse, mutect2, varscan2
- RHBDL2 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1186650352, COSV56708056; called by muse, mutect2, varscan2
- RIDA | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781008707, COSV54704689; called by mutect2, varscan2
- RIMBP2 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV55472160; called by muse, mutect2, varscan2
- RIPPLY3 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV61566695; called by muse, mutect2, varscan2
- RNF212 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); catalogued as COSV61364499; called by muse, mutect2, varscan2
- ROS1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63855077; called by muse, mutect2, varscan2
- RP1 | c.3340G>A p.G1114S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV55116574; called by muse, mutect2, varscan2
- RPH3A | c.979C>T p.P327S (on ENST00000389385 / NM_001143854.2; = p.P323S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV66990376; called by muse, mutect2
- RYR1 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761141862, COSV62091176; called by muse, mutect2, varscan2
- RYR3 | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66778566; called by muse, mutect2, varscan2
- SAMD9 | c.3800C>T p.S1267F | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV66075103; called by muse, mutect2, varscan2
- SARDH | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV64096634; called by muse, mutect2, varscan2
- SCN11A | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56570199; called by muse, mutect2, varscan2
- SCN9A | c.2747C>T p.S916F (on ENST00000303354; = p.S905F on NM_002977.3) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57609488; called by muse, mutect2, varscan2
- SCRG1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV99633482; called by muse, mutect2, varscan2
- SERPINA4 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV54069879; called by muse, mutect2, varscan2
- SERPINB11 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV66956931; called by muse, mutect2, varscan2
- SETD5 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56710904; called by muse, mutect2, varscan2
- SGCA | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56248510; called by muse, mutect2, varscan2
- SHPRH | c.4463C>T p.S1488L (on ENST00000275233 / NM_001042683.3; = p.S1492L on NM_173082.3) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771261253, COSV51609628; called by mutect2, varscan2
- SI | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52277974; called by muse, mutect2, varscan2
- SIRPB1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.492); catalogued as COSV53538681; called by muse, mutect2, varscan2
- SKIL | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV52059776; called by muse, mutect2, varscan2
- SLC10A2 | c.586-1G>A p.X196_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as rs776179675, COSV55358841; called by muse, mutect2, varscan2
- SLC13A1 | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV52011163; called by muse, mutect2, varscan2
- SLC16A3 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs771896374, COSV100012430; called by muse, mutect2, varscan2
- SLC22A10 | c.831G>T p.R277S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.392); catalogued as COSV60421254; called by muse, mutect2, varscan2
- SLC22A9 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV54167152; called by muse, varscan2
- SLC25A53 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV62458817; called by muse, mutect2, varscan2
- SLC2A12 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51599980; called by muse, mutect2, varscan2
- SLC2A2 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as COSV58586009; called by mutect2, varscan2
- SLC35G5 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | catalogued as rs1248311048, COSV55312327; called by mutect2, varscan2
- SLC4A8 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60652084; called by muse, mutect2, varscan2
- SLC9C1 | c.2702G>A p.G901D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV59888123; called by muse, mutect2, varscan2
- SLCO1B3 | c.1682+1G>A p.X561_splice | Splice Site (SNP) | VAF 28/91 reads (31%) | catalogued as COSV53937299; called by muse, varscan2
- SLITRK1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65673986, COSV65675543, COSV65676597; called by muse, mutect2, varscan2
- SMAP2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65532285; called by muse, mutect2, varscan2
- SMG1 | c.9658C>G p.P3220A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1245287151, COSV67171256; called by muse, mutect2, varscan2
- SORCS3 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as rs760140824, COSV63795020; called by mutect2, varscan2
- SORL1 | c.6328G>A p.E2110K | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV52754364; called by muse, mutect2, varscan2
- SOX7 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs1316817490, COSV58730773; called by muse, varscan2
- SPATA16 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV63529171; called by muse, mutect2, varscan2
- SPEN | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1444751567, COSV65361658; called by muse, mutect2, varscan2
- STXBP5L | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as COSV56513031; called by mutect2, varscan2
- SVIL | c.5839G>A p.E1947K (on ENST00000355867 / NM_021738.3; = p.E1521K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV63443329; called by muse, mutect2, varscan2
- SYNGR2 | c.209A>T p.Y70F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV56745705; called by muse, mutect2, varscan2
- TACR3 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59201319; called by muse, mutect2, varscan2
- TAS2R4 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV56093534; called by muse, mutect2, varscan2
- TCEAL5 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 25/41 reads (61%) | catalogued as COSV65502986, COSV65503621; called by muse, mutect2
- TDRD10 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV63812355; called by muse, mutect2, varscan2
- TENM4 | c.7970A>T p.N2657I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99574818; called by muse, mutect2, varscan2
- TFEC | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV99624500; called by muse, mutect2, varscan2
- TFEC | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV99624502; called by muse, mutect2, varscan2
- TGIF2LY | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58291693; called by muse, mutect2, varscan2
- THBS3 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64249367, COSV64250261; called by muse, mutect2, varscan2
- TLE6 | c.970C>T p.P324S (on ENST00000246112 / NM_001143986.2; = p.P201S on NM_024760.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55735527; called by muse, mutect2, varscan2
- TMC1 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs142073640, COSV52775094; ClinVar: likely benign; called by mutect2, varscan2
- TMC5 | c.2176G>A p.E726K (on ENST00000396229 / NM_001105248.1; = p.E480K on NM_024780.5) | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54903938; called by muse, mutect2, varscan2
- TMEM132B | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV54749972; called by muse, mutect2, varscan2
- TMPRSS4 | c.1283G>A p.W428* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | catalogued as COSV71109119; called by muse, mutect2, varscan2
- TRIM48 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs754486791, COSV70161112; called by mutect2, varscan2
- TRIM51 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV55266447; called by muse, varscan2
- TROAP | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57744026; called by muse, mutect2, varscan2
- TSBP1 | c.1104G>A p.M368I (on ENST00000617061; = p.M373I on NM_006781.5) | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.31); catalogued as COSV66658779; called by muse, mutect2, varscan2
- TSR2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV64308681; called by muse, mutect2, varscan2
- TTC7B | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60628167; called by mutect2, varscan2
- TTLL8 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs936808687, COSV99838321; called by muse, mutect2, varscan2
- TTN | c.79986T>A p.N26662K (on ENST00000591111; = p.N19238K on NM_003319.4) | Missense Mutation (SNP) | VAF 25/48 reads (52%) | PolyPhen probably damaging (0.997); catalogued as COSV60051900; called by muse, mutect2, varscan2
- TTN | c.48223G>A p.D16075N (on ENST00000591111; = p.D8651N on NM_003319.4) | Missense Mutation (SNP) | VAF 113/226 reads (50%) | PolyPhen benign (0.319); catalogued as COSV60051957; called by muse, mutect2, varscan2
- TTN | c.38833C>T p.P12945S (on ENST00000591111; = p.P5521S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | PolyPhen probably damaging (0.918); catalogued as COSV60052018, COSV60374910; called by muse, mutect2, varscan2
- TTN | c.12220C>G p.Q4074E (on ENST00000591111; = p.Q4028E on NM_003319.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100613627; called by muse, mutect2, varscan2
- UGGT2 | c.3856G>A p.G1286R | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65074681; called by muse, varscan2
- ULK2 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs774526845, COSV64445694; called by muse, mutect2, varscan2
- UMODL1 | c.2927C>T p.P976L (on ENST00000408910 / NM_001004416.2; = p.P1104L on NM_173568.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs748655004, COSV68569796; called by muse, mutect2, varscan2
- UNC13C | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.664); catalogued as COSV52871860; called by muse, varscan2
- UNC79 | c.3562C>T p.P1188S (on ENST00000393151 / NM_001346218.2; = p.P1011S on NM_020818.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.334); catalogued as COSV56379087; called by muse, mutect2, varscan2
- UPK1B | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV51767058; called by muse, mutect2, varscan2
- UPK3A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs1173277713, COSV53414433; called by muse, varscan2
- USF1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV57037468; called by muse, mutect2, varscan2
- USHBP1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs1426597893, COSV53103509; called by muse, mutect2, varscan2
- USP31 | c.3536C>T p.P1179L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as rs143300021, COSV54852090; called by muse, mutect2, varscan2
- VEGFC | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54594231; called by muse, mutect2, varscan2
- VPS39 | c.2629T>G p.C877G (on ENST00000348544 / NM_001301138.2; = p.C866G on NM_015289.5) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826854; called by muse, mutect2, varscan2
- VPS45 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV64887799; called by muse, mutect2, varscan2
- VTA1 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV62658877; called by mutect2, varscan2
- WDR64 | c.3176G>A p.R1059K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV63795884; called by muse, varscan2
- ZBTB4 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as rs761673519, COSV60979229; called by mutect2, varscan2
- ZCCHC2 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV54037692; called by muse, varscan2
- ZKSCAN2 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV60156547; called by muse, varscan2
- ZMAT1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.316); catalogued as COSV65658530; called by muse, mutect2, varscan2
- ZNF284 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV69691005; called by mutect2, varscan2
- ZNF286A | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.927); catalogued as COSV67844532; called by mutect2, varscan2
- ZNF286A | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as rs756583719, COSV67845084, COSV67845617; called by muse, mutect2, varscan2
- ZNF347 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV61968716; called by muse, mutect2, varscan2
- ZNF350 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV54707956; called by mutect2, varscan2
- ZNF41 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57442573; called by muse, mutect2, varscan2
- ZNF438 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs35170728; called by muse, mutect2, varscan2
- ZNF443 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV56890722; called by muse, mutect2, varscan2
- ZNF454 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60768347; called by mutect2, varscan2
- ZNF560 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.621); catalogued as COSV56867802, COSV56868852; called by mutect2, varscan2
- ZNF568 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/41 reads (32%) | PolyPhen benign (0); catalogued as COSV61741478; called by muse, mutect2, varscan2
- ZNF582 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.059); catalogued as rs1303232659, COSV56733011; called by muse, mutect2, varscan2
- ZNF582 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV100018715; called by muse, mutect2, varscan2
- ZNF675 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV63096011; called by muse, mutect2, varscan2
- ZNF681 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs752740237, COSV68074273; called by mutect2, varscan2
- ZNF831 | c.2947G>A p.G983R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs201566823, COSV64040087; called by muse, mutect2, varscan2
- ZSCAN5A | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54226565; called by muse, mutect2, varscan2
- ACSM5 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ADAM32 | c.853del p.Y285Ifs*26 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by pindel, varscan2
- CDK18 | c.969del p.T324Qfs*9 (on ENST00000506784 / NM_212503.3; = p.T294Qfs*9 on NM_002596.4) | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- ELAPOR1 | c.913_914dup p.T306Kfs*64 | Frame Shift Ins (INS) | VAF 54/245 reads (22%) | called by pindel, varscan2
- IGHA1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IGHA2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF6 | c.317_318dup p.D107Qfs*35 | Frame Shift Ins (INS) | VAF 67/203 reads (33%) | called by mutect2, pindel, varscan2
- OR2A4 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, varscan2
- SLC33A1 | c.806del p.L269* | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, varscan2
- SPOCK3 | c.22_24del p.L8del | In Frame Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- UBE2NL | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by mutect2, varscan2
- A1CF | c.1784G>A p.*595= (on ENST00000373993 / NM_138932.2; = p.*587= on NM_014576.4) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV50965175; called by mutect2, varscan2
- A2M | c.606C>T p.S202= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs1233941202, COSV59386475; called by muse, mutect2, varscan2
- AAAS | c.114C>T p.F38= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV52932278; called by muse, mutect2, varscan2
- ABCC11 | c.1497G>A p.R499= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs777449253, COSV62323019; called by muse, mutect2, varscan2
- ADAMTS17 | c.1393C>T p.L465= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs1410550041, COSV51480287; called by muse, mutect2, varscan2
- ADAMTS6 | c.3286C>T p.L1096= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV58682971; called by muse, mutect2, varscan2
- ADCY7 | c.255C>T p.V85= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs370188137; called by mutect2, varscan2
- ADCY7 | c.570G>A p.G190= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54266757; called by muse, mutect2, varscan2
- ADGRF5 | c.3171C>T p.I1057= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs151037028, COSV51932232; called by mutect2, varscan2
- AHNAK | c.3588C>T p.S1196= | Silent (SNP) | VAF 93/304 reads (31%) | catalogued as COSV57213070; called by muse, mutect2, varscan2
- AHNAK2 | c.10887G>A p.K3629= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as COSV60915103, COSV60932290; called by muse, mutect2, varscan2
- AMDHD1 | c.876C>T p.I292= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs148414685; called by muse, mutect2, varscan2
- ANGPTL6 | c.1023G>A p.G341= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV53462232; called by muse, mutect2, varscan2
- ANKRD30A | c.274C>T p.L92= (on ENST00000611781; = p.L36= on NM_052997.2) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV64608565; called by muse, varscan2
- AOX1 | c.3843C>T p.F1281= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as rs150685936; called by mutect2, varscan2
- ARHGAP36 | c.1356A>G p.R452= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV52266586; called by muse, mutect2, varscan2
- ASXL1 | c.4032C>T p.S1344= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV60107790; called by muse, mutect2, varscan2
- ATG101 | c.651C>T p.A217= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs200104884; called by muse, mutect2, varscan2
- ATG2B | c.4227A>G p.L1409= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV55890318; called by muse, mutect2, varscan2
- ATMIN | c.2190C>T p.S730= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV55146027; called by muse, mutect2, varscan2
- AUTS2 | c.2058C>T p.F686= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs776135843, COSV61400488; called by muse, mutect2, varscan2
- AXIN1 | c.2539C>T p.L847= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs149865527, COSV51987440; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2640G>A p.E880= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV63245056; called by muse, mutect2, varscan2
- C12orf66 | c.843G>A p.T281= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs748065669, COSV61323166; called by mutect2, varscan2
- C3 | c.2931G>A p.E977= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1478001477; called by muse, varscan2
- C6 | c.879C>T p.I293= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs1313242644, COSV54709963, COSV54717415; called by mutect2, varscan2
- CACNA1A | c.2178G>A p.V726= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- CACNA1C | c.4464C>T p.I1488= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV59717156; called by muse, mutect2, varscan2
- CCNB3 | c.2775C>T p.V925= | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as COSV52073497, COSV99328573; called by muse, mutect2, varscan2
- CCT8L2 | c.399G>T p.R133= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100742762, COSV63462360; called by mutect2, varscan2
- CDH4 | c.954C>T p.I318= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs999341553, COSV64654231; called by mutect2, varscan2
- CEACAM18 | c.426C>T p.S142= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs976702180, COSV67282830; called by muse, mutect2, varscan2
- CFH | c.2454C>T p.P818= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV66408401; called by muse, varscan2
- CHST4 | c.888G>A p.L296= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1477712215, COSV100632949, COSV58296475; called by muse, mutect2, varscan2
- CKAP4 | c.765C>T p.F255= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV65172530; called by mutect2, varscan2
- CLYBL | c.600C>T p.V200= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs141341905, COSV59221500; called by mutect2, varscan2
- CMYA5 | c.2514G>A p.K838= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV71405822; called by muse, mutect2, varscan2
- COL1A2 | c.54C>T p.C18= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV51957904; called by muse, varscan2
- COL24A1 | c.1857T>C p.F619= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV65306133; called by muse, mutect2, varscan2
- COL5A3 | c.2589G>A p.G863= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53410479; called by muse, mutect2, varscan2
- CORO2B | c.324G>A p.E108= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs766159237, COSV55952920; called by muse, mutect2, varscan2
- CPNE1 | c.558C>T p.N186= (on ENST00000352393; = p.N191= on NM_003915.5) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100467540; called by muse, mutect2, varscan2
- CRB1 | c.2478G>A p.K826= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV66330321; called by muse, mutect2, varscan2
- CRHR1 | c.225C>T p.V75= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53278683; called by muse, mutect2, varscan2
- CTTN | c.603C>T p.I201= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs759044304, COSV57232257; called by muse, mutect2, varscan2
- CYP21A2 | c.1182G>A p.L394= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV64478813; called by mutect2, varscan2
- CYP2C9 | c.531G>A p.V177= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as COSV53248648; called by mutect2, varscan2
- DCLK3 | c.243G>A p.E81= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV69363122; called by muse, varscan2
- DKKL1 | c.618G>A p.K206= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55562330; called by muse, varscan2
- DNAH5 | c.12276G>A p.A4092= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs763359823, COSV54223946; ClinVar: likely benign; called by muse, varscan2
- DSC1 | c.285C>T p.F95= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs770260276, COSV57145590; called by muse, mutect2, varscan2
- DSCAM | c.2103G>A p.G701= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV68026501; called by muse, mutect2, varscan2
- DSPP | c.333G>A p.G111= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV56810311; called by muse, mutect2, varscan2
- EDAR | c.978G>A p.R326= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs749981923, COSV51502766; called by muse, mutect2, varscan2
- ENPP7 | c.1155C>T p.V385= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV60386492; called by muse, mutect2, varscan2
- EPHA3 | c.1368C>T p.S456= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV100345358; called by muse, mutect2, varscan2
- ERCC4 | c.2619C>T p.I873= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs759042927, COSV61311503; called by muse, mutect2, varscan2
- FAM110C | c.369G>A p.V123= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100566944, COSV59655964; called by mutect2, varscan2
- FAM133A | c.282G>A p.K94= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV59075251; called by muse, mutect2, varscan2
- FAM3D | c.396C>T p.F132= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs766683383, COSV62558248; called by mutect2, varscan2
- FAM83B | c.846C>T p.V282= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV60922009; called by muse, mutect2, varscan2
- FAM83H | c.3501C>T p.F1167= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs781824187, COSV62027237; called by mutect2, varscan2
- FAT3 | c.5136G>A p.G1712= | Silent (SNP) | VAF 472/857 reads (55%) | catalogued as rs1304539455, COSV53108801; called by muse, mutect2, varscan2
- FBN3 | c.2286G>A p.E762= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54460326; called by muse, mutect2, varscan2
- FIG4 | c.1783C>T p.L595= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV57787527; called by muse, mutect2, varscan2
- FNDC3B | c.471C>T p.P157= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV61042007; called by muse, mutect2, varscan2
- FPR1 | c.402G>A p.Q134= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59052041; called by muse, mutect2, varscan2
- FRMD4B | c.912C>T p.F304= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs980602924, COSV68329983; called by mutect2, varscan2
- GABRR1 | c.870C>T p.F290= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs994516200, COSV65619387; called by muse, mutect2, varscan2
- GCN1 | c.723C>T p.Y241= | Silent (SNP) | VAF 54/171 reads (32%) | catalogued as rs1421746669, COSV56107619; called by muse, mutect2, varscan2
- GIMAP4 | c.546C>T p.F182= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV55431612; called by mutect2, varscan2
- GOLGB1 | c.2604T>C p.L868= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as COSV61465698; called by muse, mutect2, varscan2
- GPR87 | c.669C>T p.I223= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs149315251; called by mutect2, varscan2
- GPRC5C | c.345C>T p.I115= (on ENST00000652232; = p.I70= on NM_018653.4) | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV61236879; called by muse, mutect2, varscan2
- GRIN2A | c.2814G>A p.K938= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV58032191; called by muse, mutect2, varscan2
- GRM6 | c.1839G>A p.T613= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs765885831, COSV51440795; called by mutect2, varscan2
- HCN4 | c.3180C>T p.P1060= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV56083518; called by muse, varscan2
- HECTD1 | c.5784C>T p.H1928= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV67946276; called by muse, mutect2, varscan2
- HGD | c.1302C>T p.F434= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as COSV52198034; called by mutect2, varscan2
- HMGCLL1 | c.588G>A p.E196= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV51444662; called by muse, mutect2, varscan2
- HNRNPF | c.591C>T p.P197= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV61561005; called by muse, mutect2, varscan2
- HS3ST5 | c.957T>C p.S319= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1486041079, COSV57140125; called by muse, mutect2, varscan2
- HSCB | c.318C>T p.F106= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV53262411; called by mutect2, varscan2
- IFNL1 | c.189G>A p.L63= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV61317731; called by muse, mutect2, varscan2
- IFT122 | c.652C>T p.L218= (on ENST00000348417 / NM_052989.3; = p.L269= on NM_052985.4) | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV56202612, COSV56202967; called by muse, varscan2
- IFT140 | c.297C>T p.P99= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV68488499; called by muse, mutect2, varscan2
- IGKV1-12 | c.348C>T p.F116= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, varscan2
- IGKV6-21 | c.270C>T p.F90= | Silent (SNP) | VAF 32/56 reads (57%) | called by mutect2, varscan2
- IGSF22 | c.1644G>A p.K548= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs777671802, COSV60032549, COSV60034087; called by muse, mutect2, varscan2
- IL20RA | c.1092G>A p.S364= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs202196623, COSV57357663; called by mutect2, varscan2
- JUP | c.2076C>T p.P692= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV60277986; called by muse, mutect2, varscan2
- KCNJ11 | c.633C>T p.I211= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as COSV60594509; called by mutect2, varscan2
- KCNJ5 | c.246G>A p.V82= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV57965967; called by muse, mutect2, varscan2
- KLHL32 | c.1092T>G p.A364= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV65111981; called by muse, mutect2, varscan2
- KLHL38 | c.1416C>T p.A472= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs1175241534, COSV58087306; called by muse, mutect2, varscan2
- KLHL6 | c.1404G>A p.K468= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV58066344; called by muse, mutect2, varscan2
- KRT25 | c.294T>C p.H98= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV56444770; called by muse, varscan2
- LALBA | c.267G>A p.R89= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV56395844; called by muse, mutect2, varscan2
- LCP2 | c.1230C>T p.S410= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99252773; called by muse, mutect2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs757501135, COSV60750793; called by mutect2, varscan2
- LHX8 | c.447C>T p.V149= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV53956641, COSV99633835; called by muse, varscan2
- LRG1 | c.192C>T p.G64= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs756681034, COSV56703662; called by muse, mutect2, varscan2
- MAP1A | c.3858G>A p.R1286= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV55808647; called by muse, mutect2, varscan2
- MAP2K3 | c.720G>A p.L240= (on ENST00000342679 / NM_145109.3; = p.L211= on NM_002756.4) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57567395; called by mutect2, varscan2
- MAPK4 | c.258C>T p.P86= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs768107488, COSV68542120; called by muse, varscan2
- MGAM | c.3087C>T p.A1029= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV72074619; called by muse, mutect2, varscan2
- MICAL2 | c.4983C>T p.S1661= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV56285868; called by muse, mutect2, varscan2
- MIER2 | c.1095C>T p.V365= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53395701; called by mutect2, varscan2
- MTCL1 | c.2775C>T p.I925= (on ENST00000306329 / NM_001378206.1; = p.I565= on NM_015210.4) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs138194834, COSV60406004; called by mutect2, varscan2
- MUC16 | c.29088A>T p.G9696= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV67465130; called by muse, mutect2, varscan2
- MUC16 | c.12276C>T p.I4092= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs756263109, COSV67465143; called by muse, mutect2, varscan2
- MXRA5 | c.540C>T p.F180= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV54234827; called by mutect2, varscan2
- MYH3 | c.3393G>A p.A1131= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs767069738, COSV56864809; called by mutect2, varscan2
- MYO15A | c.1524G>A p.G508= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs764916912, COSV52756521; called by muse, varscan2
- MYO15A | c.10260C>T p.F3420= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52756531; called by mutect2, varscan2
- MYO7A | c.1701G>A p.E567= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV68684630; called by mutect2, varscan2
- NECTIN4 | c.1090C>T p.L364= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV63512664; called by muse, mutect2, varscan2
- NFASC | c.3657G>A p.E1219= (on ENST00000339876 / NM_001378329.1; = p.E1148= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1218332291, COSV58365258; called by muse, mutect2, varscan2
- NIBAN1 | c.1620C>T p.V540= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV62284661, COSV62287804; called by muse, mutect2, varscan2
- NMUR2 | c.666C>T p.F222= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV54919219, COSV99677052; called by muse, varscan2
- NTNG1 | c.1146C>T p.V382= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs992652120, COSV64271278; called by mutect2, varscan2
- OR2G3 | c.879G>A p.R293= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60681665; called by muse, mutect2, varscan2
- OR4K14 | c.408G>A p.L136= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs77403071, COSV59292837; called by mutect2, varscan2
- OR4K17 | c.36C>T p.F12= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV59648029; called by muse, varscan2
- OR51G1 | c.315C>T p.F105= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV58969176; called by mutect2, varscan2
- OR52N1 | c.135C>T p.F45= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs570634505, COSV57693354; called by mutect2, varscan2
- OR5AK2 | c.360G>A p.V120= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58804440; called by muse, mutect2, varscan2
- OR8K3 | c.501C>T p.S167= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as rs1268513314, COSV57131511; called by muse, mutect2, varscan2
- OSMR | c.2472G>A p.R824= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV57084852; called by muse, mutect2, varscan2
- P2RY10 | c.672C>G p.S224= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV50681285, COSV50683757; called by muse, mutect2, varscan2
- PAK5 | c.180A>C p.T60= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV62027139; called by muse, mutect2, varscan2
- PAK6 | c.903C>T p.S301= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1396476338, COSV53045585; called by muse, mutect2, varscan2
- PARVG | c.54C>T p.P18= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100796080, COSV63562550; called by muse, varscan2
- PCDH15 | c.4473G>A p.E1491= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV57309128; called by muse, mutect2, varscan2
- PCDH15 | c.1329T>A p.L443= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV57309151; called by mutect2, varscan2
- PCDHA6 | c.327C>T p.I109= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV100972480, COSV65349761; called by mutect2, varscan2
- PCDHA6 | c.1662C>T p.F554= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV65344058; called by muse, mutect2, varscan2
- PCDHB1 | c.2340C>T p.F780= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as rs782354216, COSV60630798; called by muse, mutect2, varscan2
- PCDHGA3 | c.2229G>A p.A743= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53945761; called by muse, varscan2
- PCNX1 | c.6939C>T p.I2313= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs142043783; called by mutect2, varscan2
- PER2 | c.2307G>A p.Q769= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV54523599; called by muse, mutect2, varscan2
- PGLYRP2 | c.1125C>T p.A375= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV52991004, COSV52992713; called by muse, mutect2, varscan2
- PIWIL2 | c.2319C>T p.S773= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as COSV100769409; called by muse, mutect2, varscan2
- PKP3 | c.1125G>A p.Q375= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1029269490, COSV58987114; called by muse, mutect2, varscan2
- PLEKHA4 | c.930C>T p.P310= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs1375532631, COSV54363039; called by muse, mutect2, varscan2
- PLXNA2 | c.4062C>T p.L1354= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV65440582; called by muse, mutect2, varscan2
- PODN | c.441C>T p.N147= (on ENST00000395871; = p.N99= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV57013515; called by muse, mutect2, varscan2
- PRAMEF1 | c.1344G>A p.K448= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1469564701, COSV60009202; called by muse, mutect2, varscan2
- PTPRD | c.2715G>A p.E905= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV61945360; called by muse, mutect2, varscan2
- RASGRP1 | c.585G>A p.R195= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1358543090, COSV60365142; called by muse, mutect2, varscan2
- RBPJL | c.39C>T p.P13= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV59213650; called by muse, mutect2, varscan2
- RGS7 | c.198G>A p.L66= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV58541404; called by mutect2, varscan2
- RIN3 | c.1374C>T p.V458= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV53648304; called by muse, varscan2
- RLF | c.4533T>C p.F1511= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV65651796; called by muse, mutect2, varscan2
- RNF103 | c.1965C>T p.G655= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV52894831; called by muse, mutect2, varscan2
- RPL7L1 | c.522C>T p.I174= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1305370153, COSV100491703; called by muse, mutect2, varscan2
- S1PR3 | c.513G>A p.L171= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV63980587; called by mutect2, varscan2
- SAMD12 | c.30G>A p.L10= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV59049479; called by mutect2, varscan2
- SAV1 | c.873C>T p.S291= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV61204879; called by muse, mutect2, varscan2
- SERPINC1 | c.567C>T p.T189= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV62929382; called by muse, mutect2, varscan2
- SLA | c.828C>T p.D276= (on ENST00000338087 / NM_001045556.3; = p.D316= on NM_006748.4) | Silent (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- SLC16A3 | c.1323G>A p.R441= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100012429; called by muse, mutect2, varscan2
- SLC22A11 | c.72C>T p.F24= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57253089; called by mutect2, varscan2
- SLC27A6 | c.1110C>T p.F370= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs746756365, COSV52481824, COSV52482901; called by mutect2, varscan2
- SLC4A10 | c.108C>T p.H36= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55778316; called by muse, mutect2, varscan2
- SNCAIP | c.1080G>A p.Q360= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV54410054; called by muse, mutect2, varscan2
- SNPH | c.447C>T p.I149= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs761585417, COSV60589326; called by mutect2, varscan2
- SORL1 | c.2838C>T p.I946= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV52754353; called by mutect2, varscan2
- SPEN | c.4875G>A p.E1625= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as COSV65361664; called by muse, mutect2, varscan2
- SSTR2 | c.837C>T p.S279= | Silent (SNP) | VAF 52/76 reads (68%) | catalogued as rs199800631, COSV59535187; called by muse, mutect2, varscan2
- SYNDIG1L | c.702G>A p.Q234= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV59047475; called by muse, mutect2, varscan2
- TAS2R38 | c.105C>T p.F35= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs144536521; called by mutect2, varscan2
- TMEM184B | c.1158C>T p.S386= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV62672577; called by muse, mutect2, varscan2
- TNFSF15 | c.414C>T p.F138= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs867957370, COSV65010140; called by muse, mutect2, varscan2
- TPRG1 | c.132G>A p.Q44= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as COSV61465027; called by muse, mutect2, varscan2
- TRAV9-1 | c.231G>A p.R77= | Silent (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- TSSK1B | c.40C>T p.L14= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs763148295, COSV66815258; called by muse, mutect2, varscan2
- UNC13C | c.3495G>A p.Q1165= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52871835; called by muse, varscan2
- UPK1B | c.255G>A p.R85= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as rs868042875, COSV51767043; called by muse, mutect2, varscan2
- VAT1L | c.447C>T p.I149= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV56819943; called by muse, mutect2, varscan2
- VSTM2A | c.39C>T p.F13= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV56493080, COSV56493986; called by muse, mutect2, varscan2
- WHRN | c.1560C>T p.V520= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV54330556; called by muse, mutect2, varscan2
- XKR3 | c.453C>T p.F151= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV58886057; called by muse, mutect2, varscan2
- ZBED9 | c.3366G>A p.K1122= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV71729396, COSV71729797; called by muse, mutect2, varscan2
- ZCWPW1 | c.117G>A p.E39= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV61248976; called by muse, mutect2, varscan2
- ZFP2 | c.576C>A p.G192= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV63725688; called by muse, mutect2, varscan2
- ZKSCAN3 | c.180C>T p.P60= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV52852511; called by muse, mutect2, varscan2
- ZNF16 | c.1716C>T p.P572= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV52763608; called by muse, mutect2, varscan2
- ZNF585B | c.1020C>T p.N340= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as COSV57215618; called by muse, mutect2, varscan2
- ZNF773 | c.1158T>G p.P386= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV56588476; called by muse, mutect2, varscan2
- ABTB1 | c.*141C>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99229823; called by muse, mutect2, varscan2
- DST | c.4297-2820G>A | Intron (SNP) | VAF 60/190 reads (32%) | catalogued as rs768205773, COSV99756115; called by muse, mutect2, varscan2
- ERBB4 | c.82+112115T>A | Intron (SNP) | VAF 21/39 reads (54%) | catalogued as COSV99623919; called by muse, mutect2, varscan2
- FGFR3 | c.*1092C>T | 3'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as rs1260819324, COSV53401273; called by muse, mutect2, varscan2
- GCNT2 | c.925+27229C>T | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100297252; called by muse, mutect2, varscan2
- GLRXP3 | n.39G>A | RNA (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- MIR520B | n.50C>T | RNA (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- NEUROD6 | c.*2G>A | 3'UTR (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99774049; called by mutect2, varscan2
- NRG1 | c.502+31321T>C | Intron (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99828445; called by muse, mutect2, varscan2
- PRRX1 | c.599+3878C>T | Intron (SNP) | VAF 95/232 reads (41%) | catalogued as COSV99509713, COSV99510476; called by muse, mutect2, varscan2
- SDR16C5 | c.*2G>A | 3'UTR (SNP) | VAF 59/187 reads (32%) | catalogued as COSV100373852; called by muse, mutect2, varscan2
- SNORD115-43 | n.67G>A | RNA (SNP) | VAF 81/253 reads (32%) | called by muse, mutect2, varscan2
- SSPOP | n.6069C>T | RNA (SNP) | VAF 4/16 reads (25%) | catalogued as rs747021671, COSV100022777, COSV50487415; called by mutect2, varscan2
- VN1R10P | n.428C>T | RNA (SNP) | VAF 58/204 reads (28%) | catalogued as rs756201585; called by muse, mutect2, varscan2
- VNN3 | c.*60G>A | 3'UTR (SNP) | VAF 19/55 reads (35%) | catalogued as COSV51590910; called by muse, mutect2, varscan2
- WASF4P | n.55C>T | RNA (SNP) | VAF 18/32 reads (56%) | called by muse, varscan2
